Somatic mutation profile of tumor specimen TARGET-10-PAPAGK-04A (aliquot TARGET-10-PAPAGK-04A-01D) from TARGET case TARGET-10-PAPAGK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (853 days).
Specimen TARGET-10-PAPAGK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02d4b72f-5c84-4773-b5e7-14cba2f0b5e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGK-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0226fba-6bd3-4988-a4ab-ab18b6c3508c

The open-access MAF lists 27 somatic variants for this specimen: 25 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 159/407 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 42/210 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.1550G>C p.R517P | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778239614, COSV56646393, COSV56646868; called by muse, mutect2, varscan2
- ANKRD30B | c.3594C>A p.N1198K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100271691; called by mutect2, varscan2
- CNTNAP5 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs200795882; called by muse, mutect2, varscan2
- DENND1B | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 161/411 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV52470542, COSV99030134; called by muse, mutect2, varscan2
- DNAJC8 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 141/405 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55282743; called by muse, mutect2, varscan2
- FAT1 | c.7411G>C p.V2471L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV101499374, COSV71675482; called by muse, mutect2, varscan2
- FLOT2 | c.1258A>T p.I420F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67529381; called by muse, mutect2, varscan2
- H1-8 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV60974409; called by muse, varscan2
- IKZF1 | c.1390T>C p.C464R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58790277; called by muse, varscan2
- NT5C2 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV58414717, COSV58414729; called by muse, mutect2, varscan2
- RCC2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs752691455, COSV64906190; called by muse, mutect2, varscan2
- RYR2 | c.4499G>A p.R1500H | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs749719028, COSV63657232; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 146/496 reads (29%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SHROOM2 | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV66609627; called by muse, mutect2, varscan2
- SYNE1 | c.18761G>A p.R6254H (on ENST00000367255 / NM_182961.4; = p.R6183H on NM_033071.3) | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs752272082, COSV55066607; ClinVar: uncertain significance; called by muse, mutect2
- TMTC1 | c.1500G>C p.K500N (on ENST00000539277 / NM_001193451.2; = p.K392N on NM_175861.3) | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.068); catalogued as COSV55490418; called by muse, mutect2, varscan2
- TNFAIP6 | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54642004; called by muse, mutect2, varscan2
- TRAK2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 224/502 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs772803564, COSV60274114; called by muse, mutect2, varscan2
- TRRAP | c.4624A>C p.T1542P (on ENST00000359863 / NM_001244580.1; = p.T1524P on NM_003496.3) | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV62851833; called by muse, varscan2
- FCGBP | c.2033C>G p.T678S | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GOLGB1 | c.8046_8049del p.K2682Nfs*2 | Frame Shift Del (DEL) | VAF 123/348 reads (35%) | called by pindel, varscan2
- NUDT15 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2
- RNF144B | c.896A>C p.D299A | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, varscan2
- MUC16 | c.22509A>G p.K7503= | Silent (SNP) | VAF 151/407 reads (37%) | catalogued as COSV67480790; called by muse, mutect2, varscan2
- SOHLH1 | c.*570G>A | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as rs1160844516, COSV53683459; called by muse, mutect2, varscan2
